Gene-level copy-number profile of tumor specimen TCGA-CV-7429-01A from TCGA case TCGA-CV-7429, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 55.3 years (20,188 days).
Specimen TCGA-CV-7429-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.fe1b8f00-7f38-441b-90a4-77beed62ceb9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-7429-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/85b9d6e2-96bb-43c8-bf20-19363ed0f988

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 246; copy number 2: 4,993; copy number 3: 21,606; copy number 4: 27,977; copy number 5: 565; copy number 6: 3,475; copy number 7: 476; copy number 8: 225; copy number 11: 73; copy number 13: 80; copy number 17: 94.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-7429-01A-11D-2128-01): tumor purity 0.52, ploidy 2.1, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 2 genes (within-gene range 0–6): MTAP, AL359922.1.
- chr9:21,858,910–21,995,301, 5 genes: AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes: AL449423.1, CDKN2B, UBA52P6.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 247 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:45,940,449–62,275,678, 247 genes, copy number 11–17 (within-gene range 3–17) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
